Gene-level copy-number profile of tumor specimen TCGA-HF-7133-01A from TCGA case TCGA-HF-7133, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2.
Specimen TCGA-HF-7133-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.60612586-bfc7-48eb-a64f-e1ca35eb1662.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HF-7133-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/45ec7b00-7970-4ace-ba2f-36351039bf8f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 123; copy number 1: 20,475; copy number 2: 30,265; copy number 3: 7,950; copy number 4: 417; copy number 5: 184; copy number 6: 308; copy number 7: 19; copy number 8: 62.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HF-7133-01A-11D-2052-01): tumor purity 0.57, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 123 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,039,761–59,529,251, 3 genes: AC092343.1, AC008833.1, NDUFB4P2.
- chr8:150,584–6,036,974, 79 genes (broad region; genes not listed).
- chr13:60,144,648–62,796,714, 27 genes: DIAPH3-AS2, RNY4P28, LINC00434, TARDBPP2, AL359920.1, TDRD3, RNA5SP31, LINC00378, EIF4A1P6, AL161901.1, RNY3P5, LINC01442, MIR3169, PCDH20, AL592490.1, LINC02339, RAC1P8, AL353765.1, LINC00358, LINC01075, LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1, AL445668.1, LINC00448.
- chr13:63,397,011–64,076,044, 12 genes (within-gene range 0–1): AL359208.1, LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355, NFYAP1.
- chr13:65,787,932–65,922,731, 2 genes: HNRNPA3P5, LINC01052.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 537 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:52,775,193–52,791,668, 1 gene, copy number 6 (within-gene range 3–6): GNPNAT1.
- chr14:52,791,756–71,321,882, 378 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr14:71,330,342–71,330,738, 1 gene, copy number 5: AC005476.1.
- chr18:34,976,928–35,711,834, 21 genes, copy number 5 (within-gene range 1–5): MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1.
- chr19:28,869,507–29,901,869, 26 genes, copy number 6: AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1.
- chr20:49,632,945–49,892,242, 6 genes, copy number 5 (within-gene range 2–5): B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1.
- chr20:55,408,898–55,684,915, 1 gene, copy number 8 (within-gene range 4–8): LINC01440.
- chr20:55,504,906–57,895,444, 52 genes, copy number 5–8: AL160413.1, AL109829.1, AL109828.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P, AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1.
- chr20:58,218,495–60,083,872, 51 genes, copy number 5–8: ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, AL160410.1, PIEZO1P1, AL389889.2, AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1.

Autosomal genes at a single copy (total copy number 1): 19,108. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
